Somatic mutation profile of tumor specimen TCGA-HU-8243-01A (aliquot TCGA-HU-8243-01A-11D-2340-08) from TCGA case TCGA-HU-8243, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 66.2 years (24,187 days).
Specimen TCGA-HU-8243-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cac6de60-f79c-4b52-9dd2-def612a15817.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-8243-10A (Blood Derived Normal), aliquot TCGA-HU-8243-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/145448b4-1588-4efd-aacf-e48015e6a720

The open-access MAF lists 131 somatic variants for this specimen: 97 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 31, Nonsense Mutation 6, In Frame Del 4, Frame Shift Ins 3, Splice Site 2, RNA 1, Frame Shift Del 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.5251C>T p.R1751* | Nonsense Mutation (SNP) | VAF 48/208 reads (23%) | catalogued as rs80357123, CM970175, COSV58785164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 33/81 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61684417, COSV61684645, COSV61684738; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 24/43 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2848dup p.H950Pfs*13 | Frame Shift Ins (INS) | VAF 36/62 reads (58%) | catalogued as rs1022557002; called by mutect2, varscan2
- AKT1 | c.1339A>G p.I447V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs764514218, COSV62572672, COSV62576349; called by muse, mutect2, varscan2
- ANKRD12 | c.583C>G p.R195G | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50819411, COSV50821436; called by muse, mutect2, varscan2
- ANKRD17 | c.2779G>A p.A927T | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV58218063; called by muse, mutect2, varscan2
- APC | c.8150G>C p.G2717A | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as rs876658201, COSV57334867; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARMC12 | c.193C>T p.R65W (on ENST00000373866 / NM_001286574.2; = p.R92W on NM_145028.5) | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.941); catalogued as rs369155496; called by muse, mutect2, varscan2
- ATP1A4 | c.2506G>A p.D836N | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs752142002, COSV63626009; called by muse, mutect2, varscan2
- BMP5 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 27/104 reads (26%) | catalogued as rs550837639, COSV63700675; called by muse, mutect2, varscan2
- BPIFB3 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs202072797, COSV64956812; called by muse, mutect2
- CDH2 | c.2609T>A p.L870* | Nonsense Mutation (SNP) | VAF 9/105 reads (9%) | catalogued as COSV99295895; called by muse, mutect2
- CDH8 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765500932, COSV54858415, COSV54909666; called by muse, mutect2, varscan2
- CDON | c.1771C>A p.P591T | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as COSV54996512; called by muse, mutect2, varscan2
- CFHR2 | c.425C>G p.S142C | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV100804194, COSV66380861; called by muse, mutect2
- CHD7 | c.1075C>G p.Q359E | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.035); catalogued as COSV71108530; called by muse, mutect2, varscan2
- COG6 | c.1587C>G p.I529M | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as rs756253977, COSV62995439, COSV62997072; called by muse, mutect2, varscan2
- CYP2A6 | c.787T>A p.S263T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs750403699, COSV56534596; called by muse, mutect2, varscan2
- CYP2A7 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs758516456, COSV52499589; called by muse, mutect2, varscan2
- DCDC1 | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.273); catalogued as COSV60838605, COSV60862353; called by muse, mutect2, varscan2
- DGCR8 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 91/317 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs1314258293, COSV61226150; called by muse, mutect2, varscan2
- DGLUCY | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56365356; called by muse, mutect2, varscan2
- DHX57 | c.3667C>G p.P1223A | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV54883732; called by muse, mutect2, varscan2
- DLC1 | c.2264C>T p.T755M (on ENST00000276297 / NM_001348081.2; = p.T318M on NM_006094.5) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201189821, COSV52297122; called by muse, mutect2, varscan2
- EFHC1 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV64135908; called by muse, mutect2, varscan2
- EIF2AK4 | c.2635G>C p.D879H | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); catalogued as COSV55466874; called by muse, mutect2, varscan2
- ERN2 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs1198969580, COSV56832546; called by muse, mutect2, varscan2
- FBXL7 | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV61643928; called by muse, mutect2, varscan2
- FRMD6 | c.531C>A p.F177L (on ENST00000344768 / NM_001267046.2; = p.F169L on NM_152330.4) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV61086370, COSV61087184; called by muse, mutect2, varscan2
- GALNT17 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV61150667; called by muse, mutect2
- GART | c.1826A>T p.D609V | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67818278; called by muse, mutect2, varscan2
- GBF1 | c.5509G>A p.E1837K (on ENST00000369983 / NM_001377137.1; = p.E1836K on NM_004193.3) | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs377647711; called by muse, mutect2, varscan2
- GLI3 | c.4610G>A p.R1537H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs746798261, COSV67886970; called by muse, mutect2, varscan2
- GPATCH8 | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1208810279, COSV59193933; called by muse, mutect2, varscan2
- GPC5 | c.1368T>A p.N456K | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.262); catalogued as COSV65588661; called by muse, mutect2, varscan2
- GPR27 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV55203431, COSV55205741; called by muse, mutect2, varscan2
- GRIK1 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.509); catalogued as rs375169701; called by muse, mutect2, varscan2
- GSTM2 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs769666982, COSV53982007; called by muse, mutect2, varscan2
- H2BC8 | c.73_75del p.K25del | In Frame Del (DEL) | VAF 28/141 reads (20%) | catalogued as rs763480943; called by pindel, varscan2
- IL6R | c.764T>G p.L255R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59815958; called by muse, mutect2, varscan2
- INTS4 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV71087685, COSV71088009; called by muse, mutect2, varscan2
- ITGB8 | c.27dup p.T10Yfs*34 | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | catalogued as rs760028800; called by mutect2, varscan2
- KCNH7 | c.1207T>C p.Y403H | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV59792200; called by muse, mutect2, varscan2
- KCTD8 | c.127C>G p.P43A | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV63587425; called by muse, mutect2
- KIF4B | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs199820075, COSV101469192, COSV70526998; called by muse, mutect2, varscan2
- KIRREL1 | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs1007075644, COSV63286155; called by muse, mutect2, varscan2
- LAMC3 | c.3649G>T p.A1217S | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs1020646051, COSV62653834; called by muse, mutect2, varscan2
- MFSD2A | c.1196C>T p.A399V (on ENST00000372809 / NM_001136493.3; = p.A386V on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139973362; called by muse, mutect2, varscan2
- MRGPRF | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as COSV100307783, COSV100307916; called by muse, varscan2
- NMD3 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs768281274, COSV63618377; called by muse, mutect2, varscan2
- NPAP1 | c.475A>G p.R159G | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.519); catalogued as COSV61505701; called by muse, mutect2, varscan2
- NSG2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs147555850; called by muse, mutect2, varscan2
- NUDT10 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.595); catalogued as rs1260568169, COSV100726783; called by mutect2, varscan2
- OR2AG2 | c.943A>G p.T315A | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as rs1337592381, COSV100643074, COSV58454878; called by muse, mutect2, varscan2
- OR52E8 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as COSV101190169, COSV66205626; called by muse, mutect2
- OR6K6 | c.86C>T p.T29M (on ENST00000368144; = p.T5M on NM_001005184.1) | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs142721506; called by muse, mutect2, varscan2
- OR9G4 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs375310727, COSV57248174; called by muse, mutect2, varscan2
- OSBP | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1335189573, COSV55661643; called by muse, mutect2, varscan2
- OSBPL8 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1326487457, COSV53880385; called by muse, mutect2, varscan2
- PCDHGB1 | c.2017G>A p.D673N | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.722); catalogued as COSV53922278; called by muse, mutect2, varscan2
- PHLPP2 | c.1184G>A p.R395K | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62423612; called by muse, mutect2, varscan2
- PLXNA1 | c.159C>G p.H53Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52524341; called by muse, mutect2, varscan2
- PPP1R3A | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs868174796, COSV52875758; called by muse, mutect2, varscan2
- RANBP6 | c.53A>C p.E18A | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV52388797; called by muse, mutect2, varscan2
- RBL1 | c.2872-1G>C p.X958_splice | Splice Site (SNP) | VAF 9/81 reads (11%) | catalogued as COSV60329175; called by muse, mutect2, varscan2
- RIMBP2 | c.2704C>T p.R902W | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777035774, COSV55464688; called by muse, mutect2, varscan2
- SACS | c.12407T>G p.L4136R | Missense Mutation (SNP) | VAF 5/115 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV66534211, COSV66534777; called by muse, mutect2
- SCGB1D1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs766448972, COSV60377334; called by muse, mutect2, varscan2
- SCGB3A2 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57023194; called by muse, mutect2, varscan2
- SDK1 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs537568518, COSV67362464; called by muse, mutect2, varscan2
- SLC35C2 | c.85A>T p.I29F | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54756455; called by muse, mutect2, varscan2
- SLITRK5 | c.1544A>G p.N515S | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61521897; called by muse, mutect2, varscan2
- SPTY2D1 | c.269A>G p.K90R | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1333996112, COSV60473441; called by muse, mutect2, varscan2
- SRRM1 | c.2337C>A p.N779K | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV60476069; called by muse, mutect2, varscan2
- TBR1 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67417546; called by muse, mutect2, varscan2
- THSD7A | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV70262850; called by muse, mutect2, varscan2
- TMEM61 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772195839, COSV64873453; called by muse, mutect2
- TMPRSS15 | c.2570G>A p.R857Q | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as rs756065153, COSV53037526; called by muse, mutect2, varscan2
- TRIAP1 | c.154A>G p.I52V | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as rs1565911147, COSV56663528; called by mutect2, varscan2
- TRIM6-TRIM34 | c.1410C>A p.C470* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | catalogued as COSV61454902; called by muse, mutect2, varscan2
- TUSC3 | c.553A>G p.R185G | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV65879719; called by muse, mutect2, varscan2
- UNC13A | c.3214C>A p.Q1072K | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV53192007; called by muse, mutect2
- WBP1L | c.135C>G p.F45L | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV64009526; called by muse, mutect2, varscan2
- WDR72 | c.2986G>A p.E996K | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64743956; called by muse, mutect2, varscan2
- XKR7 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs781185215, COSV73813083, COSV73813493; called by muse, mutect2, varscan2
- ZNF208 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV68103082, COSV68104081; called by muse, mutect2, varscan2
- ZNF571 | c.800C>G p.T267S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as rs1233032660, COSV60732723; called by muse, mutect2, varscan2
- ZPR1 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV57062449, COSV57064915; called by muse, mutect2, varscan2
- ZSCAN18 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs1429150434, COSV53731607; called by muse, mutect2, varscan2
- ADGRV1 | c.2908_2911del p.E970Wfs*9 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- ANO6 | c.740_747+14del p.X247_splice | Splice Site (DEL) | VAF 25/74 reads (34%) | called by mutect2, pindel
- DDX19B | c.593_595del p.V198_R199delinsG | In Frame Del (DEL) | VAF 56/129 reads (43%) | called by mutect2, pindel, varscan2
- DXO | c.472_504del p.G158_P168del | In Frame Del (DEL) | VAF 21/114 reads (18%) | called by mutect2, pindel
- IPO7 | c.2235_2237del p.I746del | In Frame Del (DEL) | VAF 16/55 reads (29%) | called by pindel, varscan2
- PPM1M | c.280_281dup p.E95Qfs*32 (on ENST00000296487; = p.E256Qfs*32 on NM_144641.4) | Frame Shift Ins (INS) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- TRAV8-1 | c.205T>C p.Y69H | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ACKR3 | c.81C>T p.I27= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs767699327, COSV56021110; called by muse, mutect2, varscan2
- BDKRB2 | c.117C>T p.N39= | Silent (SNP) | VAF 132/322 reads (41%) | catalogued as rs201661317, COSV60014201; called by muse, mutect2, varscan2
- CCKBR | c.438G>A p.V146= | Silent (SNP) | VAF 70/116 reads (60%) | catalogued as COSV58100051; called by muse, mutect2, varscan2
- CEACAM8 | c.753A>G p.A251= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV54990451; called by muse, mutect2, varscan2
- CHRD | c.1272C>T p.A424= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as rs1425886042, COSV52606680; called by muse, mutect2, varscan2
- CTNNA2 | c.2406G>T p.L802= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV58144317; called by muse, mutect2, varscan2
- DCAF12L2 | c.237C>G p.A79= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs750116698, COSV63580890; called by muse, mutect2, varscan2
- DLL3 | c.915C>T p.Y305= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs372702131; called by muse, mutect2, varscan2
- DMGDH | c.1299C>A p.G433= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV54862271; called by muse, mutect2, varscan2
- DMXL2 | c.8799G>A p.Q2933= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV51843160; called by muse, mutect2, varscan2
- EBF1 | c.750G>A p.S250= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs778456440, COSV58173213; called by muse, mutect2, varscan2
- FBXL7 | c.1014C>T p.S338= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs759822107, COSV61652246; called by muse, mutect2, varscan2
- GRIK3 | c.492C>T p.L164= | Silent (SNP) | VAF 92/235 reads (39%) | catalogued as rs761107716, COSV66137749; called by muse, mutect2, varscan2
- GRM7 | c.306C>T p.G102= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs765037223, COSV63137069; called by muse, mutect2, varscan2
- IQCN | c.2283G>A p.Q761= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as COSV66573269; called by muse, mutect2
- MAGEE1 | c.1866G>A p.G622= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs1556839775, COSV63909434; called by muse, mutect2, varscan2
- MS4A10 | c.327G>A p.A109= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as rs773540389, COSV57632348; called by muse, mutect2, varscan2
- NMBR | c.141G>A p.P47= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs1274355986, COSV57800789; called by muse, mutect2, varscan2
- NOTCH1 | c.5154C>T p.I1718= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs755764089, COSV53040421; called by muse, mutect2, varscan2
- PCDH10 | c.2331G>A p.A777= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV52090783; called by muse, mutect2, varscan2
- PCDHA4 | c.2046G>A p.A682= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV63540205; called by muse, mutect2, varscan2
- PLEKHG3 | c.1503A>G p.P501= (on ENST00000394691; = p.P557= on NM_001308147.2) | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV55978715; called by muse, mutect2, varscan2
- PLEKHG6 | c.1950G>A p.P650= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs200121586, COSV50599224; called by muse, mutect2, varscan2
- PNMA8B | c.1521G>A p.S507= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV66536150; called by muse, mutect2, varscan2
- POGLUT3 | c.267C>T p.V89= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV60212128; called by muse, mutect2, varscan2
- RGS9 | c.1167C>T p.D389= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs539179005, COSV52224261; called by muse, mutect2, varscan2
- RNF182 | c.327G>T p.L109= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as COSV70368977; called by muse, mutect2, varscan2
- SLC12A1 | c.1326C>T p.T442= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs769836162, COSV66793437; called by muse, mutect2, varscan2
- SYCP2 | c.210G>A p.L70= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV62767283; called by muse, mutect2, varscan2
- TACSTD2 | c.462C>T p.I154= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV64667023; called by muse, mutect2, varscan2
- UCMA | c.105G>A p.A35= | Silent (SNP) | VAF 48/159 reads (30%) | catalogued as rs1336750015, COSV66321278; called by muse, mutect2, varscan2
- DCHS2 | n.8206A>T | RNA (SNP) | VAF 18/64 reads (28%) | catalogued as COSV61769814; called by muse, mutect2, varscan2
- NRXN2 | c.3403+5680G>A | Intron (SNP) | VAF 4/20 reads (20%) | catalogued as rs747754695, COSV55450476; called by mutect2, varscan2
- PGS1 | c.*2G>A | 3'UTR (SNP) | VAF 16/99 reads (16%) | catalogued as COSV99428052; called by muse, mutect2, varscan2
